Gene-level copy-number profile of tumor specimen TCGA-CU-A3KJ-01A from TCGA case TCGA-CU-A3KJ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 75.8 years (27,692 days).
Specimen TCGA-CU-A3KJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.f4898918-fe13-4e3c-b75e-a7ae76e13289.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CU-A3KJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f49f37ab-0e9f-4827-af41-0f2a3544058f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 41; copy number 1: 396; copy number 2: 15,326; copy number 3: 23,491; copy number 4: 16,465; copy number 5: 3,401; copy number 6: 543; copy number 7: 37; copy number 8: 24; copy number 10: 34; copy number 15: 7; copy number 23: 4; copy number 24: 43; copy number 38: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CU-A3KJ-01A-11D-A219-01): tumor purity 0.75, ploidy 3.15, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 41 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,278,050–22,824,213, 39 genes: IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239.
- chr9:22,747,700–22,768,316, 2 genes: CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 150 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:147,258,885–148,288,951, 34 genes, copy number 7–15 (within-gene range 6–15): LINC00624, AC242426.1, OR13Z1P, Y_RNA, OR13Z2P, OR13Z3P, BCL9, AC242628.1, ACP6, RN7SL261P, AC241644.1, GJA5, AC241644.3, AC241644.2, AC239801.1, GJA8, GPR89B, PDZK1P1, AC239803.1, LINC02804, RNU1-129P, RNVU1-7, PDE4DIPP1, NBPF11, PFN1P4, ABHD17AP1, LINC02805, AC239809.3, RNA5SP57, AC239809.1, AC239809.2, RNVU1-22, LINC01731, AC245100.3.
- chr1:150,548,562–150,881,683, 19 genes, copy number 10: ADAMTSL4-AS2, ADAMTSL4, ADAMTSL4-AS1, MCL1, RN7SL473P, RN7SL600P, AL356356.1, ENSA, U4, GOLPH3L, HORMAD1, RNU6-1042P, CTSS, AL356292.1, CTSK, UBE2D3P3, ARNT, RNU6-1309P, RPS27AP6.
- chr1:159,276,503–159,588,865, 15 genes, copy number 10: MPTX1, OR10J2P, FCER1A, OR10J3, AL513323.1, OR10J7P, OR10J8P, OR10J9P, OR10J4, OR10J1, LINC02819, OR10J5, AL606752.1, OR10AE1P, APCS.
- chr1:162,445,549–163,769,691, 23 genes, copy number 8: SLAMF6P1, UHMK1, UQCRBP2, AL596325.1, UAP1, AL596325.2, DDR2, RN7SL861P, HSD17B7, CCDC190, AL392003.2, AL392003.1, RGS4, RGS5, RGS5-AS1, AL451063.1, RGS5, AL592435.1, NUF2, AL603841.1, RNA5SP62, RNA5SP63, AL355862.1.
- chr11:69,000,765–70,436,584, 46 genes, copy number 23–24: AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,604,859, 2 genes, copy number 24–38: AP001271.1, AP001271.2.
- chr12:22,409,237–23,188,807, 10 genes, copy number 7 (within-gene range 3–7): AC053513.1, C2CD5, AC053513.2, LRRC34P1, AC087241.1, AC087241.2, ETNK1, AC084816.1, RPS27P22, AC084819.1.
- chr12:44,008,620–44,010,143, 1 gene, copy number 8: ZNF75BP.

Autosomal genes at a single copy (total copy number 1): 386. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
